Gene-level copy-number profile of tumor specimen TCGA-DD-AADN-01A from TCGA case TCGA-DD-AADN, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 59.2 years (21,632 days).
Specimen TCGA-DD-AADN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.69809bef-e1a4-45a0-9fa2-1e026ea2a15c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9461f1e3-a0eb-45c9-9fc5-9812aa44ca87

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,199; copy number 2: 9,151; copy number 3: 29,645; copy number 4: 12,254; copy number 5: 1,581; copy number 6: 294; copy number 7: 1,076; copy number 10: 233; copy number 12: 876; copy number 13: 237; copy number 14: 253; copy number 16: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADN-01A-11D-A40Q-01): tumor purity 0.55, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,695 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:18,408,680–53,813,733, 723 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:42,043,504–145,066,685, 1,590 genes, copy number 10–16 (broad region; genes not listed).
- chr16:85,027,751–90,222,851, 195 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:26,981,694–30,360,566, 187 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
